Somatic mutation profile of tumor specimen TCGA-17-Z018-01A (aliquot TCGA-17-Z018-01A-01W-0746-08) from TCGA case TCGA-17-Z018, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59494bb2-eb5d-477e-9c09-86caecf3b73a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z018-11A (Solid Tissue Normal), aliquot TCGA-17-Z018-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7a36ec5-b563-4c0d-9bbf-a738c9db06c0

The open-access MAF lists 268 somatic variants for this specimen: 207 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 55, Nonsense Mutation 16, Splice Site 8, Frame Shift Del 5, RNA 3, Intron 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 66/163 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACCS | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746480191; called by muse, mutect2, varscan2
- ADAMTS12 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100710237; called by muse, mutect2, varscan2
- ADGRL3 | c.994G>T p.D332Y (on ENST00000506720 / NM_001322402.2; = p.D264Y on NM_015236.6) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268204; called by mutect2, varscan2
- ALMS1 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 68/351 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.23); catalogued as COSV100042751; called by muse, mutect2, varscan2
- BDKRB2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as rs1464178755, COSV60013711; called by muse, mutect2, varscan2
- BMS1 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 37/184 reads (20%) | catalogued as COSV104423977, COSV65735833; called by muse, mutect2, varscan2
- CDKL3 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.226); catalogued as COSV54739704; called by muse, mutect2
- CKAP4 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as rs1200218780; called by muse, mutect2, varscan2
- COL11A1 | c.1738-1G>T p.X580_splice | Splice Site (SNP) | VAF 28/95 reads (29%) | catalogued as COSV62190227; called by muse, mutect2, varscan2
- COL19A1 | c.336del p.K114Rfs*10 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | catalogued as COSV100506685; called by mutect2, pindel, varscan2
- COQ8B | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360823578; called by muse, mutect2
- DCHS1 | c.6448G>T p.G2150* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55040502; called by muse, mutect2, varscan2
- DNAAF3 | c.119C>A p.T40K (on ENST00000524407 / NM_001256715.2; = p.T87K on NM_178837.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs1411405445; called by muse, mutect2
- DNAH11 | c.4095+3G>A | Splice Region (SNP) | VAF 22/117 reads (19%) | catalogued as rs375356107; called by muse, mutect2, varscan2
- DNAH9 | c.12530A>G p.Y4177C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361164; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- ELP4 | c.715G>C p.E239Q (on ENST00000350638; = p.E238Q on NM_019040.5) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV63356734; called by muse, mutect2, varscan2
- FAM47B | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs375492603, COSV61457204; called by muse, mutect2, varscan2
- FAT3 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53078094; called by muse, mutect2, varscan2
- FAT3 | c.10345G>T p.A3449S | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV53087882; called by muse, mutect2, varscan2
- FBN2 | c.3092C>A p.A1031E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs754884110, COSV52530512; called by muse, mutect2, varscan2
- FBXL7 | c.681C>A p.N227K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV61647905; called by muse, mutect2, varscan2
- FBXW7 | c.1438G>T p.D480Y (on ENST00000281708 / NM_001349798.2; = p.D400Y on NM_018315.5) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55923864, COSV55955907; called by muse, mutect2, varscan2
- FECH | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1270069816, COSV100023328; called by muse, mutect2, varscan2
- FLG | c.11228G>A p.R3743Q | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as rs199995422, COSV64241859; called by muse, mutect2, varscan2
- GABRG1 | c.98del p.G33Efs*15 | Frame Shift Del (DEL) | VAF 17/117 reads (15%) | catalogued as COSV54950313; called by mutect2, pindel, varscan2
- GRIN3A | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758465991, COSV62451769; called by muse, mutect2, varscan2
- GTF2IRD2B | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57032294; called by muse, mutect2, varscan2
- HDAC9 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV67771814; called by muse, mutect2, varscan2
- JADE3 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471332; called by muse, mutect2, varscan2
- KCNK2 | c.766G>C p.A256P (on ENST00000444842 / NM_001017425.3; = p.A241P on NM_014217.4) | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67204248; called by muse, mutect2, varscan2
- KCNU1 | c.1940G>T p.R647L | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756080668, COSV104433476; called by muse, mutect2, varscan2
- KEAP1 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV50634510; called by muse, mutect2, varscan2
- KIR2DL1 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs765219636; called by muse, mutect2, varscan2
- KRTAP6-2 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | PolyPhen benign (0); catalogued as COSV58183177; called by muse, mutect2, varscan2
- LYZL1 | c.374G>T p.S125I (on ENST00000375500; = p.S79I on NM_032517.6) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201641133; called by muse, mutect2, varscan2
- MECP2 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as CM1111542; called by muse, mutect2, varscan2
- MEGF10 | c.2407G>C p.D803H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99174943; called by muse, mutect2, varscan2
- METTL25 | c.1349G>T p.R450L | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV50259661; called by muse, mutect2
- MMP27 | c.342-1G>T p.X114_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99498740; called by muse, mutect2, varscan2
- MSR1 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV50506878; called by muse, mutect2, varscan2
- MXRA5 | c.6996G>T p.K2332N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766565747; called by muse, mutect2, varscan2
- MYBL1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs781379946; called by muse, mutect2, varscan2
- MYH15 | c.2383A>G p.K795E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs769557794; called by muse, mutect2, varscan2
- MYLK3 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs576887058; called by muse, mutect2, varscan2
- MYT1L | c.3016C>A p.P1006T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67704158; called by mutect2, varscan2
- NES | c.3037C>A p.H1013N | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs758969972; called by muse, mutect2, varscan2
- NKX6-1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55684444; called by muse, mutect2, varscan2
- NLE1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345914904, COSV62603716; called by muse, mutect2, varscan2
- NTRK2 | c.1949A>G p.Q650R (on ENST00000323115 / NM_001369534.1; = p.Q666R on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52881450; called by mutect2, varscan2
- OR10Q1 | c.957C>A p.N319K | Missense Mutation (SNP) | VAF 83/455 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57469858; called by muse, mutect2, varscan2
- OR52J3 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.099); catalogued as rs1458728124, COSV66746505, COSV66746579; called by muse, mutect2, varscan2
- OVCH1 | c.2554G>T p.E852* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV58964588; called by muse, mutect2
- PASD1 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs772767181; called by muse, mutect2, varscan2
- PAX4 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs779638012; called by muse, mutect2, varscan2
- PCDHGB3 | c.1934C>A p.T645N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs1170186099; called by muse, mutect2, varscan2
- PEG3 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs145933493; called by muse, mutect2, varscan2
- PKHD1L1 | c.12272C>A p.A4091E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs756504072; called by muse, mutect2, varscan2
- PLCB1 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1175470388; called by muse, mutect2, varscan2
- PREX1 | c.2791G>T p.G931C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100906238; called by muse, mutect2, varscan2
- PTPRH | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.217); catalogued as COSV54745937; called by muse, mutect2, varscan2
- RAG2 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as COSV57557355; called by muse, mutect2
- RHBG | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs774514973, COSV54803104; called by muse, mutect2, varscan2
- RIMBP2 | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55476511; called by muse, mutect2, varscan2
- SEPTIN3 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs751238686; called by muse, mutect2
- SLITRK2 | c.1852C>A p.L618M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59424181; called by muse, mutect2, varscan2
- SPON1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs868948493; called by muse, mutect2, varscan2
- STAB1 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.75); catalogued as rs759568021; called by muse, mutect2, varscan2
- TRIP12 | c.4322G>A p.G1441E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52264541; called by muse, mutect2, varscan2
- VSX1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749037614, COSV65021624; called by muse, mutect2, varscan2
- WDR53 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs775116661; called by muse, mutect2, varscan2
- ZBTB7C | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59688280; called by muse, mutect2, varscan2
- ZFHX4 | c.3274G>T p.D1092Y | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51476621; called by muse, mutect2, varscan2
- ZNF835 | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73379561; called by muse, mutect2, varscan2
- ABCA12 | c.4381A>C p.R1461= (on ENST00000272895 / NM_173076.3; = p.R1143= on NM_015657.3) | Splice Region (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- ACSM2A | c.1174G>T p.V392L (on ENST00000219054; = p.V313L on NM_001308169.2) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ACSM2A | c.1175T>A p.V392E (on ENST00000219054; = p.V313E on NM_001308169.2) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM2 | c.1299C>A p.C433* | Nonsense Mutation (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- ADRB2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFP | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ALDH4A1 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMPH | c.1145G>T p.W382L | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- APMAP | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARHGEF17 | c.4162G>T p.G1388C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARR3 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASXL3 | c.4423G>T p.V1475F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6AP2 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ATP6AP2 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4537G>T p.G1513C | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.551); called by muse, varscan2
- CALCRL | c.937G>C p.V313L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- CASP4 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CBLIF | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by mutect2, varscan2
- CCDC30 | c.1995G>T p.R665S (on ENST00000340612; = p.R622S on NM_001080850.3) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CEP112 | c.2443G>T p.A815S (on ENST00000392769 / NM_001353127.1; = p.A71S on NM_001037325.3) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CHD6 | c.5683G>T p.E1895* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- CLTCL1 | c.3881G>T p.G1294V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNOT7 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2C19 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAAF1 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- DOCK9 | c.2501G>T p.C834F (on ENST00000376460 / NM_001366676.2; = p.C835F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, varscan2
- DRD2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DRD5 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG3 | c.2521C>A p.L841M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EDRF1 | c.2503C>G p.Q835E (on ENST00000356792 / NM_001202438.2; = p.Q801E on NM_015608.2) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EHBP1 | c.2930C>T p.S977L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- EPAS1 | c.201_202del p.H67Qfs*9 | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | called by pindel, varscan2
- EPB42 | c.844C>G p.L282V (on ENST00000441366 / NM_001114134.2; = p.L312V on NM_000119.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM181B | c.173A>T p.D58V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- FRMPD3 | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- GRIK3 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GUCY2F | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 93/481 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HEATR1 | c.1716-1G>T p.X572_splice | Splice Site (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- HECTD2 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC2 | c.7976G>T p.G2659V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPSE2 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IHO1 | c.1619C>A p.S540Y | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IL33 | c.89del p.G30Efs*16 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- IL4I1 | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- INTS6L | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- IQCB1 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- IRS4 | c.3211G>C p.V1071L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- JADE3 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KIAA1958 | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- KLHL4 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- KSR1 | c.1209G>T p.R403S (on ENST00000644974 / NM_001367810.1; = p.R266S on NM_014238.2) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.4714G>T p.V1572F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- LAMB4 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHFPL6 | c.359T>A p.V120E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- LILRA1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC3B | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LRRIQ4 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRTM3 | c.573C>G p.N191K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM14B | c.928T>A p.C310S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MAGEB1 | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEX3C | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MICAL2 | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MKRN3 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MOCS3 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSRA | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MTUS2 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NHS | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- NLRP3 | c.2988C>A p.C996* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- NMUR2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRXN1 | c.3350C>A p.P1117Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- NUP160 | c.1180-2A>T p.X394_splice | Splice Site (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- OCRL | c.479T>A p.L160* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- OGDHL | c.1773C>A p.C591* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- OPN5 | c.758T>A p.V253E | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR10A4 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- OR2T6 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6B3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- OR6K2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR8B2 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSBPL8 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCDH15 | c.5114C>T p.P1705L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2
- PDZD7 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZRN4 | c.2444A>T p.K815M (on ENST00000402685 / NM_001164595.2; = p.K557M on NM_013377.4) | Missense Mutation (SNP) | VAF 111/569 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- PIGO | c.2386G>T p.V796L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PIP4P1 | c.690+1G>T p.X230_splice | Splice Site (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- POF1B | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- POGLUT3 | c.1364A>G p.H455R | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- POTEF | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PPT2 | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM14 | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRKD2 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PTPRC | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRT | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RC3H2 | c.2233G>T p.V745L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX6 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPTN | c.1206C>A p.H402Q | Missense Mutation (SNP) | VAF 474/1263 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUVBL2 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by mutect2, varscan2
- RYR2 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SCN10A | c.4595A>T p.Q1532L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SCN3A | c.968-1G>T p.X323_splice | Splice Site (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- SCN5A | c.5079C>A p.N1693K (on ENST00000333535 / NM_198056.3; = p.N1692K on NM_000335.5) | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SH3PXD2A | c.2820C>A p.N940K (on ENST00000369774 / NM_001365079.1; = p.N912K on NM_014631.2) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SHLD1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC10A2 | c.20G>T p.C7F | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC8A3 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.3656A>T p.K1219M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SPEF2 | c.176A>T p.K59I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- ST8SIA5 | c.188_203del p.L63Rfs*3 | Frame Shift Del (DEL) | VAF 39/292 reads (13%) | called by mutect2, pindel, varscan2
- SYN3 | c.1380G>C p.R460S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TACC2 | c.6421A>T p.T2141S (on ENST00000334433; = p.T219S on NM_006997.4) | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TACO1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TBC1D8 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TBL2 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TEX44 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- TNRC18 | c.6710A>G p.Q2237R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRAPPC11 | c.1288-2A>T p.X430_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TRIO | c.6466-1G>T p.X2156_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- UBAC2 | c.176G>T p.C59F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UROC1 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP15 | c.1999C>T p.Q667* (on ENST00000280377 / NM_001351159.2; = p.Q638* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- USP44 | c.1760A>C p.K587T | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP20 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- WASF1 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR27 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- XPR1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- YWHAG | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDBF2 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF268 | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- ZNF507 | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF592 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 42/251 reads (17%) | called by muse, mutect2, varscan2
- ZNF776 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF804A | c.3502C>T p.Q1168* | Nonsense Mutation (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- AC231657.3 | c.699C>T p.G233= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ACOXL | c.1413G>T p.S471= (on ENST00000389811 / NM_001371254.1; = p.S441= on NM_001142807.4) | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4776G>T p.V1592= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- ADNP2 | c.1971C>T p.P657= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs141229292; called by muse, mutect2, varscan2
- APOB | c.6108C>A p.I2036= | Silent (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
- CD177 | c.435G>T p.G145= | Silent (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- CEP120 | c.2689C>A p.R897= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs777687497, COSV60265385; called by muse, mutect2, varscan2
- CHD6 | c.5682G>T p.T1894= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100951272; called by muse, mutect2, varscan2
- CHIT1 | c.516C>T p.T172= | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as COSV55145198; called by muse, mutect2, varscan2
- CNTN1 | c.2643C>A p.V881= | Silent (SNP) | VAF 77/437 reads (18%) | catalogued as COSV61638408; called by muse, mutect2, varscan2
- COL6A3 | c.3885G>T p.V1295= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- DGKK | c.306C>A p.A102= | Silent (SNP) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- DHRS9 | c.219C>A p.T73= | Silent (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- DLG2 | c.1245G>T p.L415= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- EPHB6 | c.2985C>A p.T995= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV63892767; called by muse, mutect2
- ESF1 | c.1887G>T p.L629= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- EXT1 | c.1458G>T p.A486= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as rs765275156, COSV65484516; called by muse, mutect2, varscan2
- FLG | c.10206G>A p.R3402= | Silent (SNP) | VAF 118/330 reads (36%) | catalogued as rs770361839, COSV64245634; called by muse, mutect2, varscan2
- FLRT2 | c.1536C>A p.A512= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV58152320; called by muse, mutect2, varscan2
- FUNDC2 | c.531G>T p.G177= | Silent (SNP) | VAF 37/208 reads (18%) | catalogued as COSV65671700; called by muse, mutect2, varscan2
- GABRA3 | c.951C>G p.T317= | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- GRIA3 | c.2508G>T p.G836= | Silent (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- IFIT1B | c.1303C>A p.R435= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as COSV65663371; called by muse, mutect2, varscan2
- IQGAP3 | c.2673G>T p.L891= | Silent (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- ITIH1 | c.654C>A p.A218= | Silent (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- KCNJ3 | c.1239C>T p.P413= | Silent (SNP) | VAF 48/246 reads (20%) | catalogued as rs1413769614, COSV54541339; called by muse, mutect2, varscan2
- KCNS2 | c.1068G>A p.E356= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- KLHL3 | c.219C>T p.P73= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- KRTAP9-8 | c.78C>A p.T26= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- NEO1 | c.3300G>T p.L1100= | Silent (SNP) | VAF 101/424 reads (24%) | called by muse, mutect2, varscan2
- NHLRC2 | c.1758A>G p.E586= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as rs1354704126; called by muse, mutect2, varscan2
- NUP98 | c.4644A>G p.L1548= (on ENST00000359171 / NM_001365126.1; = p.L1531= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs774458907, COSV61438027; called by muse, mutect2, varscan2
- OR10Q1 | c.102C>G p.L34= | Silent (SNP) | VAF 50/317 reads (16%) | catalogued as COSV100372352; called by muse, mutect2, varscan2
- PCDH17 | c.3267C>A p.P1089= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV64979072; called by muse, mutect2, varscan2
- POLG | c.1791G>T p.R597= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- POLR3E | c.954G>T p.A318= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV55403126; called by muse, mutect2
- PRUNE1 | c.507A>T p.A169= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- PTPN5 | c.1155C>T p.R385= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- QSER1 | c.1401A>G p.T467= (on ENST00000399302; = p.T596= on NM_001076786.3) | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- REN | c.1185G>T p.R395= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- RNASEL | c.1434C>T p.S478= | Silent (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- RTL9 | c.243A>T p.V81= | Silent (SNP) | VAF 113/632 reads (18%) | called by muse, mutect2, varscan2
- SDK2 | c.6321G>T p.S2107= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV101168785; called by muse, mutect2, varscan2
- SEL1L2 | c.18G>C p.L6= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- SLC18A2 | c.774G>T p.L258= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- SOCS6 | c.168C>A p.I56= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- SON | c.3303G>C p.R1101= | Silent (SNP) | VAF 7/63 reads (11%) | called by mutect2, varscan2
- SUCO | c.3258C>T p.G1086= | Silent (SNP) | VAF 122/397 reads (31%) | called by muse, mutect2, varscan2
- TRPC3 | c.543C>A p.L181= (on ENST00000379645 / NM_001366479.2; = p.L108= on NM_003305.2) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV53373330; called by muse, mutect2, varscan2
- TRPM8 | c.660C>A p.V220= | Silent (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- TSPEAR | c.1470G>T p.L490= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- VPS39 | c.2418G>A p.K806= (on ENST00000348544 / NM_001301138.2; = p.K795= on NM_015289.5) | Silent (SNP) | VAF 11/68 reads (16%) | called by mutect2, varscan2
- VTN | c.9C>A p.P3= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- ZNF234 | c.75G>T p.L25= | Silent (SNP) | VAF 47/235 reads (20%) | called by muse, mutect2, varscan2
- ZP4 | c.1206C>A p.V402= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4242C>A | RNA (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- CCDC34 | c.606+77G>T | Intron (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- LIM2 | c.-2C>G | 5'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- MIR891B | n.3T>A | RNA (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- MIR892A | n.37C>A | RNA (SNP) | VAF 37/299 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10361-4887A>T | Intron (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
